Gene-level copy-number profile of tumor specimen TCGA-CV-6933-01A from TCGA case TCGA-CV-6933, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.4 years (19,518 days).
Specimen TCGA-CV-6933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fe3675eb-6c9b-4f01-82a4-99a6b6d25145.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6933-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/985d2ab8-9728-47ee-a734-58654705a6fe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 739; copy number 2: 18,361; copy number 3: 15,933; copy number 4: 17,515; copy number 5: 4,668; copy number 6: 799; copy number 7: 872; copy number 8: 343; copy number 9: 10; copy number 10: 429; copy number 15: 17; copy number 18: 33; copy number 19: 1; copy number 25: 9; copy number 43: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6933-01A-11D-1910-01): tumor purity 0.48, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.
- chr3:62,118,300–62,124,608, 2 genes: RNU2-10P, ID2B.
- chr5:59,528,861–59,529,251, 1 gene: NDUFB4P2.
- chr8:4,317,388–4,329,027, 1 gene: AC027251.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 576 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,891,837–57,074,664, 110 genes, copy number 18–43 (broad region; genes not listed).
- chr7:86,216,785–106,036,432, 439 genes, copy number 10–25 (within-gene range 6–25) (broad region; genes not listed).
- chr7:108,554,543–110,592,204, 17 genes, copy number 10–19: THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2.
- chr9:29,636,486–29,826,711, 2 genes, copy number 9: AL354676.1, ME2P1.
- chr11:84,545,131–85,021,655, 8 genes, copy number 9: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6.

Autosomal genes at a single copy (total copy number 1): 497. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
